Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A1PX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A1PX-01A (Primary Tumor).

Project #
TSS1

ICD-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9 3/2/11 *per*

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1		23		Caucasian (White)	Melanoma		Male		Skin	Primary	Tumor	Tissue	Frozen
		23		Caucasian (White)	Melanoma		Male		Blood	n/a	normal	Blood	Frozen
Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	200	mg	Surgery	Melanoma	n/a	2	0	1	no	no	no	85
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

Source: NCI Genomic Data Commons file f73a234d-17af-4b07-88d4-1ef7a7d39e8e (TCGA-BF-A1PX.4BF0286A-D82F-4ACF-AE53-4B03518D2362.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).